Somatic mutation profile of tumor specimen TCGA-EB-A553-01A (aliquot TCGA-EB-A553-01A-12D-A27K-08) from TCGA case TCGA-EB-A553, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 62.9 years (22,972 days).
Specimen TCGA-EB-A553-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3594dae5-7750-4b70-9032-20b051deb086.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EB-A553-10A (Blood Derived Normal), aliquot TCGA-EB-A553-10A-01D-A27N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bf78650a-6777-4748-8284-a356b63af06d

The open-access MAF lists 377 somatic variants for this specimen: 269 protein-altering or splice-affecting, 100 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 243, Silent 100, Nonsense Mutation 15, Splice Site 5, RNA 3, Intron 2, Splice Region 2, 3'Flank 2, Frame Shift Del 2, Frame Shift Ins 1, In Frame Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1B | c.3496C>T p.Q1166* | Nonsense Mutation (SNP) | VAF 17/60 reads (28%) | catalogued as rs1554231904, COSV51666413; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 75/167 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- MSH2 | c.2038C>T p.R680* | Nonsense Mutation (SNP) | VAF 18/67 reads (27%) | catalogued as rs63749932, CM970977, COSV51875657; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACTN4 | c.1442+1G>A p.X481_splice | Splice Site (SNP) | VAF 22/82 reads (27%) | catalogued as COSV53148800; called by muse, mutect2, varscan2
- ACVRL1 | c.323C>T p.P108L | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as COSV66360690; called by muse, mutect2, varscan2
- ADAM15 | c.437C>T p.T146I | Missense Mutation (SNP) | VAF 24/165 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.45); catalogued as COSV55061823; called by muse, mutect2, varscan2
- ADCY6 | c.3095C>T p.T1032M | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57167028; called by muse, mutect2, varscan2
- ADGRB3 | c.4034T>G p.V1345G | Missense Mutation (SNP) | VAF 59/93 reads (63%) | SIFT tolerated (0.4); PolyPhen benign (0.028); catalogued as COSV53255127; called by muse, mutect2, varscan2
- ADGRD1 | c.458C>T p.S153F | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV55443627; called by muse, mutect2, varscan2
- ADGRF5 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs528282523, COSV51932406; called by muse, mutect2, varscan2
- ADGRG4 | c.8522T>C p.V2841A | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54963272; called by muse, mutect2, varscan2
- AGO4 | c.118C>T p.P40S | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as COSV64618111; called by muse, mutect2, varscan2
- AIF1 | c.55C>A p.Q19K | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.304); catalogued as COSV61962641; called by muse, mutect2, varscan2
- ALPG | c.270G>A p.M90I | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.363); catalogued as COSV54967508; called by muse, mutect2, varscan2
- ANTXR2 | c.242C>T p.S81F | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55020111; called by muse, mutect2, varscan2
- ARHGEF11 | c.4143G>A p.M1381I | Missense Mutation (SNP) | VAF 97/176 reads (55%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV59356747; called by muse, mutect2, varscan2
- ARID2 | c.4685C>T p.P1562L | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV57609643, COSV57611100; called by muse, mutect2, varscan2
- ARPP21 | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 60/127 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.148); catalogued as COSV51798623; called by muse, mutect2, varscan2
- ASB5 | c.605G>A p.G202E | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV56668428; called by muse, mutect2, varscan2
- ATF7IP2 | c.1466C>T p.P489L | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV61094761; called by muse, mutect2, varscan2
- ATP13A4 | c.1589T>G p.M530R | Missense Mutation (SNP) | VAF 33/172 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV55073033; called by muse, mutect2, varscan2
- B4GALT3 | c.343C>T p.R115C | Missense Mutation (SNP) | VAF 138/258 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.059); catalogued as rs775570899, COSV60527210; called by muse, mutect2, varscan2
- BBOX1 | c.736C>T p.P246S | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.711); catalogued as rs1267366394, COSV54192975; called by muse, mutect2, varscan2
- BCKDHB | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs374642431; called by muse, mutect2, varscan2
- BCL11B | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 34/218 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.191); catalogued as COSV61735288; called by muse, mutect2, varscan2
- BCL9L | c.2236C>T p.R746W | Missense Mutation (SNP) | VAF 37/134 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs762653904, COSV52688581; called by muse, mutect2, varscan2
- BSDC1 | c.826C>T p.P276S | Missense Mutation (SNP) | VAF 42/177 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.894); catalogued as COSV61981597; called by muse, mutect2, varscan2
- C1orf127 | c.1865T>G p.V622G | Missense Mutation (SNP) | VAF 50/161 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.041); catalogued as COSV65438287; called by muse, mutect2, varscan2
- C6 | c.1484G>A p.R495K | Missense Mutation (SNP) | VAF 53/136 reads (39%) | SIFT tolerated (0.56); PolyPhen benign (0.036); catalogued as COSV54715060; called by muse, mutect2, varscan2
- C6orf15 | c.454C>T p.P152S | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.202); catalogued as COSV52539547; called by muse, mutect2, varscan2
- CACNA1E | c.6865G>A p.G2289R (on ENST00000367573 / NM_001205293.3; = p.G2246R on NM_000721.4) | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.894); catalogued as rs750533768, COSV62409794; called by muse, mutect2, varscan2
- CAST | c.92C>A p.T31N | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs778505100, COSV57788281; called by muse, mutect2, varscan2
- CATSPERB | c.2014T>A p.L672I | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated (0.28); PolyPhen benign (0.026); catalogued as COSV56431900; called by muse, mutect2, varscan2
- CCKBR | c.1246C>T p.R416C | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.462); catalogued as rs753026530, COSV58103993; called by muse, mutect2, varscan2
- CD151 | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs913313056, COSV58990306; called by muse, mutect2, varscan2
- CDH16 | c.112C>T p.P38S | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV55338638; called by muse, mutect2, varscan2
- CDH18 | c.246C>G p.D82E | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as COSV56947199; called by muse, mutect2, varscan2
- CDH5 | c.1402G>A p.E468K | Missense Mutation (SNP) | VAF 55/206 reads (27%) | SIFT tolerated (0.81); PolyPhen benign (0.03); catalogued as COSV58519125; called by muse, mutect2, varscan2
- CFAP300 | c.793G>C p.D265H | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV71570920; called by muse, mutect2, varscan2
- CFAP70 | c.809A>C p.N270T | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV60285629; called by muse, mutect2, varscan2
- CGREF1 | c.287C>T p.S96F | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV53151291; called by muse, mutect2, varscan2
- CHERP | c.2513G>A p.R838K | Missense Mutation (SNP) | VAF 43/224 reads (19%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.899); catalogued as COSV52226824; called by muse, mutect2, varscan2
- CIC | c.3572C>T p.S1191F | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.936); catalogued as COSV99358667; called by muse, mutect2, varscan2
- CILP | c.1853G>A p.G618E | Missense Mutation (SNP) | VAF 41/151 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56026724; called by muse, mutect2, varscan2
- CIP2A | c.1523G>A p.R508H | Missense Mutation (SNP) | VAF 96/264 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs199536917, COSV55420513; called by muse, mutect2, varscan2
- COL11A1 | c.320C>T p.P107L | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.767); catalogued as COSV62191298; called by muse, mutect2, varscan2
- COL11A2 | c.1391G>A p.G464D (on ENST00000341947 / NM_080680.3; = p.G357D on NM_080679.2) | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100553243; called by muse, mutect2, varscan2
- COL11A2 | c.1390G>C p.G464R (on ENST00000341947 / NM_080680.3; = p.G357R on NM_080679.2) | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100553245; called by muse, mutect2, varscan2
- COL20A1 | c.3181G>C p.V1061L | Missense Mutation (SNP) | VAF 21/28 reads (75%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV58924074; called by muse, mutect2, varscan2
- CRB1 | c.4075C>T p.L1359F | Missense Mutation (SNP) | VAF 59/93 reads (63%) | SIFT tolerated (0.1); PolyPhen benign (0.109); catalogued as rs1427358329, COSV66345710; called by muse, mutect2, varscan2
- CUBN | c.6763C>T p.P2255S | Missense Mutation (SNP) | VAF 57/73 reads (78%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV100912778, COSV64723148; called by muse, mutect2, varscan2
- CYP26A1 | c.414+2T>C p.X138_splice | Splice Site (SNP) | VAF 79/265 reads (30%) | catalogued as COSV56419443; called by muse, mutect2, varscan2
- CYP4F12 | c.1267G>A p.D423N | Missense Mutation (SNP) | VAF 37/186 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs1304089121, COSV61173081; called by muse, mutect2, varscan2
- DDX19B | c.677C>T p.S226F | Missense Mutation (SNP) | VAF 39/68 reads (57%) | SIFT tolerated (0.86); PolyPhen benign (0.001); catalogued as COSV55365186; called by muse, mutect2, varscan2
- DKKL1 | c.620G>A p.G207E | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (1); catalogued as rs780527392, COSV55563123; called by muse, mutect2
- DMTF1 | c.56T>G p.V19G | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.767); catalogued as COSV58687374; called by muse, mutect2, varscan2
- DNAH5 | c.8653A>G p.T2885A | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV54213750, COSV54242758; called by muse, mutect2, varscan2
- DNAH5 | c.7835A>C p.H2612P | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); catalogued as COSV54242765, COSV54256926; called by muse, mutect2, varscan2
- DNAJC21 | c.100A>T p.K34* | Nonsense Mutation (SNP) | VAF 32/57 reads (56%) | catalogued as COSV57761876; called by muse, mutect2, varscan2
- DNER | c.1004C>T p.S335F | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV59162499; called by muse, mutect2
- DPF2 | c.287C>T p.P96L | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.7); PolyPhen probably damaging (0.997); catalogued as COSV52890728; called by muse, mutect2, varscan2
- DSC3 | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64574456; called by muse, mutect2, varscan2
- DSP | c.8371C>T p.R2791C | Missense Mutation (SNP) | VAF 181/470 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs867430601, COSV100673059, COSV60938692; called by muse, mutect2, varscan2
- DST | c.11323A>G p.S3775G (on ENST00000361203 / NM_001374722.1; = p.S1363G on NM_015548.5) | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV55031462; called by muse, mutect2, varscan2
- DSTYK | c.2056C>G p.P686A | Missense Mutation (SNP) | VAF 53/251 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.392); catalogued as COSV65687720; called by muse, mutect2, varscan2
- DUOX2 | c.2830G>A p.G944S | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.682); catalogued as rs143124929; called by muse, mutect2, varscan2
- EHHADH | c.1678C>A p.P560T | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.982); catalogued as COSV51632155; called by muse, mutect2, varscan2
- EP400 | c.2950C>T p.P984S | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as COSV57781397; called by muse, mutect2, varscan2
- EPHA3 | c.1150C>T p.P384S | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60699578, COSV60715314; called by muse, mutect2, varscan2
- EPN3 | c.260C>T p.T87M | Missense Mutation (SNP) | VAF 64/206 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs368660081, COSV52141916; called by muse, mutect2, varscan2
- EPPK1 | c.1610C>T p.S537F | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as rs1554661252, COSV73261857; called by muse, mutect2
- ERCC6 | c.1548G>T p.R516S | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.902); catalogued as COSV63393122; called by muse, mutect2, varscan2
- ERICH3 | c.2560G>T p.G854W | Missense Mutation (SNP) | VAF 40/161 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as COSV58606652; called by muse, mutect2, varscan2
- EXOSC9 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 42/89 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as rs755032675, COSV54667369; called by muse, mutect2, varscan2
- F12 | c.929G>A p.R310K | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV53692522; called by muse, mutect2, varscan2
- F5 | c.3089G>A p.R1030Q | Missense Mutation (SNP) | VAF 55/382 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs758795781, COSV63121240; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAHD2B | c.638C>T p.T213I | Missense Mutation (SNP) | VAF 51/133 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV55631828; called by muse, mutect2, varscan2
- FAT4 | c.532C>T p.R178C | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.545); catalogued as COSV67895306; called by muse, mutect2, varscan2
- FAT4 | c.1126G>A p.V376M | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs752356296, COSV67895313; called by muse, mutect2, varscan2
- FBLIM1 | c.196C>T p.P66S | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV60031080; called by muse, mutect2, varscan2
- FBN2 | c.901T>G p.C301G | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52533788; called by muse, mutect2, varscan2
- FGD5 | c.1921G>A p.D641N | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.372); catalogued as rs374414426; called by muse, mutect2, varscan2
- FNDC1 | c.1894C>T p.R632C | Missense Mutation (SNP) | VAF 37/77 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.548); catalogued as rs747951612, COSV51944566; called by muse, mutect2, varscan2
- FSIP2 | c.18533T>A p.I6178K | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV58094714; called by muse, mutect2, varscan2
- FTMT | c.164C>T p.S55F | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as COSV58420997; called by muse, mutect2, varscan2
- GALT | c.830C>T p.S277F | Missense Mutation (SNP) | VAF 95/239 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as COSV100535218; called by muse, mutect2, varscan2
- GCM2 | c.1297C>T p.P433S | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.014); catalogued as COSV65276263; called by muse, mutect2, varscan2
- GCN1 | c.2708C>T p.S903F | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT tolerated (0.73); PolyPhen benign (0.1); catalogued as COSV56112604; called by muse, mutect2, varscan2
- GIMAP1 | c.896C>T p.A299V | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); catalogued as COSV56187624; called by muse, mutect2, varscan2
- GIT1 | c.979C>T p.Q327* | Nonsense Mutation (SNP) | VAF 89/167 reads (53%) | catalogued as COSV56403535; called by muse, mutect2, varscan2
- GPR63 | c.173C>T p.S58F | Missense Mutation (SNP) | VAF 47/79 reads (59%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs1291836304, COSV57742714; called by muse, mutect2, varscan2
- GRM3 | c.416C>A p.P139Q | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV64477123; called by muse, mutect2, varscan2
- HCFC1 | c.1246C>A p.P416T | Missense Mutation (SNP) | VAF 78/116 reads (67%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as COSV60075730; called by muse, mutect2, varscan2
- HDAC4 | c.1447C>T p.Q483* | Nonsense Mutation (SNP) | VAF 12/26 reads (46%) | catalogued as COSV61872560; called by muse, mutect2, varscan2
- HERPUD2 | c.1012G>A p.V338I | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV60946521; called by muse, mutect2, varscan2
- HK2 | c.2273T>C p.L758P | Missense Mutation (SNP) | VAF 28/147 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV51878039; called by muse, mutect2, varscan2
- HNRNPA2B1 | c.793G>A p.G265R (on ENST00000354667 / NM_031243.3; = p.G253R on NM_002137.4) | Missense Mutation (SNP) | VAF 56/152 reads (37%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); catalogued as COSV61160603; called by muse, mutect2, varscan2
- HS3ST3A1 | c.973C>T p.R325C | Missense Mutation (SNP) | VAF 24/168 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs534065954, COSV99403908; called by muse, varscan2
- IGSF22 | c.974-2A>G p.X325_splice | Splice Site (SNP) | VAF 20/66 reads (30%) | catalogued as COSV60037107; called by mutect2, varscan2
- INSR | c.1519A>G p.T507A | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.063); catalogued as COSV57169709; called by muse, mutect2, varscan2
- IP6K2 | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 64/268 reads (24%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.72); catalogued as rs775587404, COSV60794797; called by muse, mutect2, varscan2
- IRF5 | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 69/161 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.906); catalogued as COSV50859865; called by muse, mutect2, varscan2
- IRX4 | c.576G>A p.W192* | Nonsense Mutation (SNP) | VAF 69/254 reads (27%) | catalogued as COSV51474221; called by muse, mutect2, varscan2
- IZUMO1 | c.563A>C p.Q188P | Missense Mutation (SNP) | VAF 35/178 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.095); catalogued as COSV55807115; called by muse, mutect2, varscan2
- JSRP1 | c.94G>T p.E32* | Nonsense Mutation (SNP) | VAF 9/73 reads (12%) | catalogued as COSV55560049; called by muse, mutect2, varscan2
- KCNA7 | c.754C>T p.P252S | Missense Mutation (SNP) | VAF 40/138 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55504124; called by muse, mutect2, varscan2
- KCNJ13 | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 41/213 reads (19%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.803); catalogued as rs370613677; called by muse, mutect2, varscan2
- KCNT2 | c.1546C>T p.H516Y | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.219); catalogued as COSV54098526; called by muse, mutect2, varscan2
- KRT38 | c.338A>C p.D113A | Missense Mutation (SNP) | VAF 74/142 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as COSV55847051; called by muse, mutect2, varscan2
- KRTAP24-1 | c.576T>G p.C192W | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.673); catalogued as COSV61089901; called by muse, mutect2, varscan2
- LAMP5 | c.664+1G>A p.X222_splice | Splice Site (SNP) | VAF 22/37 reads (59%) | catalogued as COSV55717476; called by muse, mutect2, varscan2
- LEFTY1 | c.223G>A p.G75R | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.996); catalogued as rs146054726; called by muse, mutect2, varscan2
- LILRB1 | c.293G>A p.R98K (on ENST00000427581; = p.R62K on NM_006669.6) | Missense Mutation (SNP) | VAF 95/281 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as COSV61116334; called by muse, mutect2, varscan2
- LILRB4 | c.563T>C p.V188A | Missense Mutation (SNP) | VAF 35/177 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV54407543; called by muse, mutect2, varscan2
- LMTK2 | c.3481G>C p.D1161H | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs761806620, COSV52001113; called by muse, mutect2, varscan2
- LRRC30 | c.535C>T p.P179S | Missense Mutation (SNP) | VAF 82/130 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67302085; called by muse, mutect2, varscan2
- LRRIQ3 | c.1495G>A p.E499K | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as COSV100599576, COSV63042485; called by muse, mutect2, varscan2
- LYST | c.10343C>T p.T3448I | Missense Mutation (SNP) | VAF 122/184 reads (66%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); catalogued as rs780701390, COSV67711339; called by muse, mutect2, varscan2
- MAGI2 | c.3160C>T p.P1054S | Missense Mutation (SNP) | VAF 120/658 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV62667514, COSV62685564; called by muse, mutect2, varscan2
- MAGOHB | c.85C>T p.R29W | Missense Mutation (SNP) | VAF 36/155 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV57898632, COSV57899083; called by muse, mutect2, varscan2
- MAP2 | c.795G>A p.W265* | Nonsense Mutation (SNP) | VAF 22/95 reads (23%) | catalogued as COSV52302304; called by muse, mutect2, varscan2
- MARCHF1 | c.310C>T p.R104C (on ENST00000274056; = p.R87C on NM_017923.4) | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs146337383; called by muse, mutect2, varscan2
- MCM7 | c.1945G>A p.G649R | Missense Mutation (SNP) | VAF 38/279 reads (14%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV57998127; called by muse, mutect2, varscan2
- MFSD2A | c.1273G>A p.D425N (on ENST00000372809 / NM_001136493.3; = p.D412N on NM_032793.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as rs1038441258, COSV65685506; called by muse, mutect2, varscan2
- MUC15 | c.799G>A p.D267N | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.068); catalogued as COSV55552569; called by muse, mutect2, varscan2
- MUC16 | c.32681C>T p.P10894L | Missense Mutation (SNP) | VAF 32/168 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.112); catalogued as COSV67452301, COSV67481919; called by muse, mutect2, varscan2
- MUC16 | c.26377C>T p.H8793Y | Missense Mutation (SNP) | VAF 70/148 reads (47%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.211); catalogued as COSV67481920; called by muse, mutect2, varscan2
- MUC5B | c.4963G>A p.E1655K | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.81); PolyPhen benign (0.006); catalogued as COSV71594377; called by muse, mutect2, varscan2
- MYH13 | c.1801G>A p.D601N | Missense Mutation (SNP) | VAF 39/76 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV52837409; called by muse, mutect2, varscan2
- MYH8 | c.2011C>A p.H671N | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV67965246, COSV67970009; called by muse, mutect2, varscan2
- MYO5B | c.4907C>T p.T1636I | Missense Mutation (SNP) | VAF 57/105 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.558); catalogued as COSV99543131; called by muse, mutect2, varscan2
- NAA16 | c.1870C>T p.Q624* | Nonsense Mutation (SNP) | VAF 26/39 reads (67%) | catalogued as COSV65127312, COSV65129318; called by muse, mutect2, varscan2
- NCAM2 | c.1629A>C p.K543N | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.85); catalogued as COSV53093690; called by muse, mutect2, varscan2
- NCKAP1L | c.2633T>A p.L878H | Missense Mutation (SNP) | VAF 87/196 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53210446; called by muse, mutect2, varscan2
- NDOR1 | c.1609C>T p.L537F (on ENST00000371521 / NM_001144026.3; = p.L521F on NM_014434.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); catalogued as COSV61289393; called by muse, mutect2, varscan2
- NDST4 | c.1940+2T>G p.X647_splice | Splice Site (SNP) | VAF 10/63 reads (16%) | catalogued as COSV52130692; called by muse, mutect2, varscan2
- NECTIN1 | c.395G>A p.G132D | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50604849; called by muse, mutect2, varscan2
- NES | c.3025C>T p.P1009S | Missense Mutation (SNP) | VAF 107/632 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.045); catalogued as COSV63962254; called by muse, mutect2, varscan2
- NFIB | c.229C>T p.L77F | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV66621189; called by muse, mutect2, varscan2
- NFKBIA | c.488T>G p.L163R | Missense Mutation (SNP) | VAF 32/168 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV53754027; called by muse, mutect2, varscan2
- NFKBIB | c.473C>T p.P158L | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV58004433; called by muse, mutect2, varscan2
- NHSL2 | c.1811G>C p.S604T (on ENST00000510661; = p.S970T on NM_001013627.2) | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV65454420; called by muse, mutect2
- NIBAN1 | c.1628A>C p.E543A | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV62286828; called by muse, mutect2, varscan2
- NID2 | c.2173A>C p.N725H | Missense Mutation (SNP) | VAF 19/140 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.497); catalogued as COSV53500641; called by muse, mutect2, varscan2
- NLRP5 | c.629C>T p.S210L | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.017); catalogued as rs1453888678, COSV66766494; called by muse, mutect2, varscan2
- NPPA | c.212G>A p.G71E | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.335); catalogued as COSV56742160; called by muse, mutect2, varscan2
- NUAK2 | c.76G>A p.G26R | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.006); catalogued as COSV65682286; called by muse, mutect2, varscan2
- NUMB | c.808C>G p.Q270E (on ENST00000355058; = p.Q259E on NM_003744.5) | Missense Mutation (SNP) | VAF 33/152 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.16); catalogued as COSV61830576, COSV61831383; called by muse, mutect2, varscan2
- OR13C8 | c.339G>T p.M113I | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1445546186, COSV100623048, COSV58611198, COSV58611995; called by muse, mutect2, varscan2
- OR2C1 | c.408G>A p.M136I | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.047); catalogued as rs1450893776, COSV59240930; called by muse, mutect2, varscan2
- OR2T6 | c.227C>T p.T76I | Missense Mutation (SNP) | VAF 68/114 reads (60%) | SIFT tolerated (0.15); PolyPhen benign (0.034); catalogued as COSV63216882; called by muse, mutect2, varscan2
- OR4C15 | c.508G>A p.A170T (on ENST00000314644; = p.A116T on NM_001001920.2) | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.047); catalogued as rs755144556, COSV58954597; called by muse, mutect2, varscan2
- OR4K14 | c.830C>T p.T277I | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.708); catalogued as COSV59293798; called by muse, mutect2, varscan2
- OR4Q3 | c.314G>A p.G105E | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV59179306; called by muse, mutect2, varscan2
- OR8H2 | c.481G>A p.V161I | Missense Mutation (SNP) | VAF 44/192 reads (23%) | SIFT tolerated (0.52); PolyPhen benign (0.012); catalogued as COSV57946703; called by muse, mutect2, varscan2
- PAK5 | c.1339G>A p.E447K | Missense Mutation (SNP) | VAF 50/153 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.071); catalogued as COSV62027703; called by muse, mutect2, varscan2
- PCDHA2 | c.1129C>T p.R377C | Missense Mutation (SNP) | VAF 42/129 reads (33%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.276); catalogued as rs781879420, COSV65369803; called by muse, mutect2, varscan2
- PCDHB3 | c.2314C>T p.P772S | Missense Mutation (SNP) | VAF 59/120 reads (49%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.249); catalogued as COSV50606311; called by muse, mutect2, varscan2
- PCDHB7 | c.1616C>T p.P539L | Missense Mutation (SNP) | VAF 52/178 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50798706; called by muse, mutect2, varscan2
- PCDHGB7 | c.1084C>T p.P362S | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT tolerated (0.22); PolyPhen benign (0.192); catalogued as rs751344893, COSV54001589; called by muse, mutect2, varscan2
- PCSK5 | c.2153A>C p.N718T | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.508); catalogued as COSV100949986, COSV65093619; called by muse, mutect2, varscan2
- PDZD2 | c.6806C>T p.P2269L | Missense Mutation (SNP) | VAF 76/220 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99223114; called by muse, mutect2, varscan2
- PGLYRP3 | c.528G>T p.K176N | Missense Mutation (SNP) | VAF 123/176 reads (70%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.88); catalogued as COSV51951856; called by muse, mutect2, varscan2
- PHLDB2 | c.3089C>T p.S1030L (on ENST00000393925 / NM_001134439.2; = p.S987L on NM_145753.2) | Missense Mutation (SNP) | VAF 26/172 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as COSV67314600; called by muse, varscan2
- PIGZ | c.688T>G p.F230V | Missense Mutation (SNP) | VAF 19/155 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53014315; called by muse, mutect2, varscan2
- PIP5K1B | c.1357G>A p.A453T | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV99597676; called by muse, mutect2, varscan2
- PIWIL1 | c.2164G>A p.D722N | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.026); catalogued as COSV55350129; called by muse, mutect2, varscan2
- PKD1L1 | c.1274G>A p.G425E | Missense Mutation (SNP) | VAF 45/83 reads (54%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.864); catalogued as COSV56973482; called by muse, mutect2, varscan2
- PKD2L2 | c.587G>C p.R196P | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV51795868, COSV51800113; called by muse, mutect2, varscan2
- PLCL1 | c.2383C>T p.R795C | Missense Mutation (SNP) | VAF 72/170 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868552410, COSV101407023, COSV70822134; called by muse, mutect2, varscan2
- PLEKHA5 | c.451A>G p.K151E | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV54708573; called by muse, mutect2, varscan2
- POLA1 | c.4385C>T p.S1462F | Missense Mutation (SNP) | VAF 16/21 reads (76%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.023); catalogued as COSV66889353; called by muse, mutect2, varscan2
- POLQ | c.4688C>T p.S1563F | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV51758161; called by muse, mutect2, varscan2
- POLR3A | c.2032G>C p.D678H | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.743); catalogued as COSV64931713; called by muse, mutect2, varscan2
- PPCS | c.376C>T p.P126S | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.1); catalogued as COSV65333504; called by muse, mutect2, varscan2
- PPP2R5B | c.721C>T p.R241W | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs775505111, COSV51209688; called by muse, mutect2, varscan2
- PRDM9 | c.1482G>T p.M494I | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV57010376, COSV57010765; called by muse, mutect2, varscan2
- PREX2 | c.4577T>C p.I1526T | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.185); catalogued as rs1329040912, COSV55790976; called by muse, mutect2, varscan2
- PRLR | c.1619C>T p.P540L | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as COSV51498664; called by muse, mutect2, varscan2
- PRR12 | c.2585C>T p.P862L (on ENST00000615927; = p.P1683L on NM_020719.3) | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.831); catalogued as COSV69819332; called by muse, mutect2, varscan2
- PSMA5 | c.719A>C p.D240A | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV54749362; called by muse, mutect2, varscan2
- PTGER3 | c.1081G>A p.E361K (on ENST00000628037 / NM_198717.2; = p.E370K on NM_198716.2) | Missense Mutation (SNP) | VAF 48/218 reads (22%) | SIFT tolerated, low confidence (0.94); PolyPhen benign (0); catalogued as rs771757558, COSV63388000; called by muse, mutect2, varscan2
- PTPN4 | c.2144C>T p.P715L | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV55306372; called by muse, mutect2, varscan2
- PTPRJ | c.1010C>T p.P337L | Missense Mutation (SNP) | VAF 33/133 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.743); catalogued as COSV69253739; called by muse, mutect2, varscan2
- PTPRT | c.548G>T p.R183L | Missense Mutation (SNP) | VAF 27/196 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0.176); catalogued as COSV61995746, COSV61999444, COSV62005537; called by muse, mutect2, varscan2
- R3HCC1L | c.197C>A p.P66Q | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.225); catalogued as COSV54400393, COSV54404050; called by muse, mutect2, varscan2
- RADX | c.542T>A p.L181* | Nonsense Mutation (SNP) | VAF 47/139 reads (34%) | catalogued as COSV65319663; called by muse, mutect2, varscan2
- RANGRF | c.229G>A p.A77T | Missense Mutation (SNP) | VAF 62/111 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV56839962; called by muse, mutect2, varscan2
- REPS1 | c.769C>T p.R257* | Nonsense Mutation (SNP) | VAF 24/43 reads (56%) | catalogued as rs892384615, COSV57812975; called by muse, mutect2, varscan2
- RICTOR | c.2700T>C p.N900= | Splice Region (SNP) | VAF 36/170 reads (21%) | catalogued as COSV57127699; called by muse, mutect2, varscan2
- RITA1 | c.638C>G p.P213R | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.332); catalogued as COSV55323001; called by muse, mutect2, varscan2
- RPP25 | c.512G>A p.R171K | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.027); catalogued as COSV59120298; called by muse, mutect2, varscan2
- RUBCN | c.2062C>T p.R688C | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV56364306; called by muse, mutect2, varscan2
- RUNX1T1 | c.1505T>A p.L502Q (on ENST00000265814 / NM_001198628.1; = p.L475Q on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/58 reads (60%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.514); catalogued as COSV56157263; called by muse, mutect2, varscan2
- SCN9A | c.3932T>G p.V1311G (on ENST00000303354; = p.V1300G on NM_002977.3) | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57618985; called by muse, mutect2, varscan2
- SDK2 | c.4121G>C p.R1374P | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV101166570; called by muse, mutect2, varscan2
- SEC23A | c.1069C>T p.L357F | Missense Mutation (SNP) | VAF 45/234 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); catalogued as rs1170026307, COSV56977097; called by muse, mutect2, varscan2
- SENP2 | c.1468T>G p.C490G | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.591); catalogued as COSV56196494; called by muse, mutect2
- SH2D2A | c.1133G>A p.R378K | Missense Mutation (SNP) | VAF 111/200 reads (56%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); catalogued as COSV63885230; called by muse, mutect2, varscan2
- SH3GL1 | c.363G>T p.M121I | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.497); catalogued as COSV53658931; called by muse, mutect2, varscan2
- SI | c.3688C>T p.R1230C | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs560337003, COSV52266879, COSV52289363; called by muse, mutect2, varscan2
- SIPA1L3 | c.4148C>T p.S1383F | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.212); catalogued as rs1268016047, COSV55921027; called by muse, mutect2, varscan2
- SLAMF9 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.219); catalogued as COSV63637093; called by muse, mutect2, varscan2
- SLC12A5 | c.3131C>T p.P1044L (on ENST00000454036 / NM_001134771.2; = p.P1021L on NM_020708.5) | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as rs1206199358, COSV51646355; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC17A8 | c.1646G>A p.G549E | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as COSV60124008; called by muse, mutect2, varscan2
- SLC1A6 | c.652T>C p.S218P | Missense Mutation (SNP) | VAF 29/150 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV55672623; called by muse, mutect2, varscan2
- SLC27A3 | c.1205C>T p.S402F (on ENST00000271857; = p.S274F on NM_024330.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV55165068; called by muse, mutect2, varscan2
- SLC44A5 | c.1687G>A p.E563K | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV63770918; called by muse, mutect2
- SLFN12 | c.1174C>T p.P392S | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs1321986266, COSV100513116, COSV59227102; called by muse, mutect2, varscan2
- SORL1 | c.3370C>T p.R1124C | Missense Mutation (SNP) | VAF 37/124 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs267602736, COSV52750742; called by muse, mutect2, varscan2
- SORL1 | c.5444C>T p.S1815F | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.084); catalogued as COSV52759492; called by muse, mutect2, varscan2
- SOWAHC | c.831T>A p.D277E | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.066); catalogued as COSV61781416; called by muse, mutect2, varscan2
- SP5 | c.73C>A p.P25T | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV64623609; called by muse, mutect2, varscan2
- SPTB | c.4300G>A p.E1434K | Missense Mutation (SNP) | VAF 84/227 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.093); catalogued as COSV67633956; called by muse, mutect2, varscan2
- STRN3 | c.1285A>G p.M429V (on ENST00000357479 / NM_001083893.2; = p.M345V on NM_014574.4) | Missense Mutation (SNP) | VAF 40/203 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs1050453092, COSV62581204; called by muse, mutect2, varscan2
- SV2C | c.343G>A p.D115N | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.087); catalogued as rs149119749, COSV59221082, COSV59225859; called by muse, mutect2, varscan2
- SVEP1 | c.1321C>T p.L441F | Missense Mutation (SNP) | VAF 57/115 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as rs754739184, COSV57043652; called by muse, mutect2, varscan2
- TAF5 | c.2140G>A p.V714I | Missense Mutation (SNP) | VAF 97/180 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV58916178; called by muse, mutect2, varscan2
- TBXAS1 | c.961C>T p.P321S | Missense Mutation (SNP) | VAF 51/93 reads (55%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs779880644, COSV54951003; called by muse, mutect2, varscan2
- TCIM | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 46/75 reads (61%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.701); catalogued as COSV59928201; called by muse, mutect2, varscan2
- TECTA | c.2471C>T p.T824I | Missense Mutation (SNP) | VAF 41/164 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.023); catalogued as COSV50765467; called by muse, mutect2, varscan2
- TENM1 | c.1757G>A p.G586E | Missense Mutation (SNP) | VAF 214/289 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64439077; called by muse, mutect2, varscan2
- TEX101 | c.472C>A p.P158T (on ENST00000598265 / NM_001130011.3; = p.P176T on NM_031451.4) | Missense Mutation (SNP) | VAF 37/191 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV53662724; called by muse, mutect2, varscan2
- TEX13B | c.797C>T p.S266F | Missense Mutation (SNP) | VAF 59/172 reads (34%) | SIFT tolerated (0.56); PolyPhen benign (0.12); catalogued as COSV57203605; called by muse, mutect2, varscan2
- TJP1 | c.4061A>G p.Y1354C | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV62044727; called by muse, mutect2, varscan2
- TLE3 | c.437C>T p.P146L | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.703); catalogued as COSV58172935; called by muse, mutect2, varscan2
- TMEM183A | c.461C>T p.S154F | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs966185999, COSV65887977; called by muse, mutect2, varscan2
- TNN | c.2402A>C p.Q801P | Missense Mutation (SNP) | VAF 32/171 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.116); catalogued as COSV53432269; called by muse, mutect2, varscan2
- TRAPPC9 | c.1658G>A p.R553Q | Missense Mutation (SNP) | VAF 29/131 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.026); catalogued as rs745348155, COSV66906513; called by muse, mutect2, varscan2
- TRAV10 | c.54G>A p.R18= | Splice Region (SNP) | VAF 29/61 reads (48%) | catalogued as rs773310881; called by muse, mutect2, varscan2
- TRIM55 | c.361C>T p.Q121* | Nonsense Mutation (SNP) | VAF 28/65 reads (43%) | catalogued as rs1240599419, COSV52549214; called by muse, mutect2, varscan2
- TRPV6 | c.566G>T p.G189V | Missense Mutation (SNP) | VAF 32/204 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63892957; called by muse, mutect2, varscan2
- TTN | c.97063A>G p.T32355A (on ENST00000591111; = p.T24931A on NM_003319.4) | Missense Mutation (SNP) | VAF 21/95 reads (22%) | PolyPhen probably damaging (0.989); catalogued as COSV60239812; called by muse, mutect2, varscan2
- TTN | c.71840G>A p.G23947E (on ENST00000591111; = p.G16523E on NM_003319.4) | Missense Mutation (SNP) | VAF 53/191 reads (28%) | PolyPhen benign (0.062); catalogued as COSV60239852; called by muse, mutect2, varscan2
- TTN | c.24532G>A p.E8178K (on ENST00000591111; = p.E7251K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/70 reads (40%) | PolyPhen possibly damaging (0.84); catalogued as rs868344900, COSV60239887; called by muse, mutect2, varscan2
- UBN2 | c.502G>A p.D168N | Missense Mutation (SNP) | VAF 30/199 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV56033895; called by muse, mutect2, varscan2
- UBXN2A | c.124G>T p.E42* | Nonsense Mutation (SNP) | VAF 40/131 reads (31%) | catalogued as COSV58337446; called by muse, mutect2, varscan2
- USP19 | c.1703C>T p.S568F | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60047611; called by muse, mutect2, varscan2
- USP34 | c.6761C>T p.S2254L | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as rs1558485553, COSV68398995; called by muse, mutect2, varscan2
- VPS13B | c.3670C>T p.Q1224* | Nonsense Mutation (SNP) | VAF 70/147 reads (48%) | catalogued as COSV62152254; called by muse, mutect2, varscan2
- VWA8 | c.4720G>A p.G1574R | Missense Mutation (SNP) | VAF 27/45 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV64998914; called by muse, mutect2, varscan2
- WDR59 | c.2153C>T p.P718L | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50940966; called by muse, mutect2, varscan2
- WNK2 | c.4711G>A p.D1571N (on ENST00000297954 / NM_001282394.1; = p.D1534N on NM_006648.3) | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99940544; called by muse, mutect2, varscan2
- WNK3 | c.5354C>T p.P1785L | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); catalogued as rs782613910, COSV63615303; called by muse, mutect2, varscan2
- WNT9A | c.844C>T p.P282S | Missense Mutation (SNP) | VAF 51/83 reads (61%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as COSV55296434; called by muse, mutect2, varscan2
- WWTR1 | c.889G>A p.D297N | Missense Mutation (SNP) | VAF 63/463 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.172); catalogued as rs1233273169, COSV62292383; called by muse, mutect2, varscan2
- XDH | c.140G>C p.G47A | Missense Mutation (SNP) | VAF 26/184 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.335); catalogued as COSV65150456; called by muse, mutect2, varscan2
- XPOT | c.2349T>G p.N783K | Missense Mutation (SNP) | VAF 39/205 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.134); catalogued as rs200929597, COSV60347193; called by muse, mutect2, varscan2
- ZBED6CL | c.247G>A p.G83R | Missense Mutation (SNP) | VAF 42/264 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1286449945, COSV59605185; called by muse, mutect2, varscan2
- ZBTB39 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 29/164 reads (18%) | SIFT tolerated (0.63); PolyPhen benign (0.045); catalogued as COSV55630267; called by muse, mutect2, varscan2
- ZC3H3 | c.2600C>T p.P867L | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.026); catalogued as rs759842599, COSV52786881, COSV52793151; called by muse, mutect2, varscan2
- ZC3H6 | c.2353C>T p.P785S | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1487606753, COSV59669738; called by muse, mutect2, varscan2
- ZFYVE26 | c.2494C>T p.P832S | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.31); catalogued as COSV61331858; called by muse, mutect2, varscan2
- ZNF175 | c.542T>G p.M181R | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as COSV51797404; called by muse, mutect2, varscan2
- ZNF20 | c.1486C>T p.H496Y | Missense Mutation (SNP) | VAF 61/245 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62000132; called by muse, mutect2, varscan2
- ZNF205 | c.854A>G p.E285G | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV54622311; called by muse, mutect2, varscan2
- ZNF296 | c.75G>A p.M25I | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as COSV54320376; called by muse, mutect2, varscan2
- ZNF300 | c.1613G>T p.G538V | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.42); PolyPhen benign (0.018); catalogued as COSV51043302; called by muse, mutect2, varscan2
- ZNF354A | c.1270C>T p.R424* | Nonsense Mutation (SNP) | VAF 16/79 reads (20%) | catalogued as rs552131359, COSV59984247; called by muse, mutect2, varscan2
- ZNF607 | c.1359A>T p.E453D | Missense Mutation (SNP) | VAF 70/132 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV62206036; called by muse, mutect2, varscan2
- ZNF800 | c.589G>C p.E197Q | Missense Mutation (SNP) | VAF 19/184 reads (10%) | SIFT tolerated (0.52); PolyPhen benign (0.051); catalogued as rs1477997467, COSV56173825; called by muse, mutect2, varscan2
- ZSCAN1 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs771402043, COSV56607021; called by muse, mutect2, varscan2
- ANK3 | c.3699_3707del p.Y1234_G1236del (on ENST00000280772 / NM_001320874.2; = p.Y368_G370del on NM_001149.3) | In Frame Del (DEL) | VAF 23/70 reads (33%) | called by mutect2, pindel, varscan2
- FMNL2 | c.320dup p.R108Kfs*10 | Frame Shift Ins (INS) | VAF 5/24 reads (21%) | called by mutect2, pindel, varscan2
- IGHE | c.595G>A p.G199S | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- PCF11 | c.2281_2311del p.A761Kfs*6 | Frame Shift Del (DEL) | VAF 22/119 reads (18%) | called by mutect2, pindel
- RB1 | c.429del p.V144Lfs*9 | Frame Shift Del (DEL) | VAF 18/48 reads (38%) | called by mutect2, pindel, varscan2
- SUPT20HL1 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 33/57 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- TRAC | c.75C>G p.F25L | Missense Mutation (SNP) | VAF 46/196 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- ALAS2 | c.120C>T p.I40= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as rs1297057453, COSV58192540; called by muse, mutect2, varscan2
- ANXA10 | c.90C>T p.L30= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as COSV63739816; called by muse, mutect2, varscan2
- ARID1B | c.3495C>T p.L1165= | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as COSV99266419; called by muse, mutect2, varscan2
- ATP12A | c.282C>T p.S94= | Silent (SNP) | VAF 175/371 reads (47%) | catalogued as rs752157792, COSV54517586; called by muse, mutect2, varscan2
- ATP13A1 | c.1581C>T p.V527= | Silent (SNP) | VAF 14/74 reads (19%) | catalogued as rs770200385, COSV52289681; called by muse, mutect2, varscan2
- ATP2B3 | c.2505C>T p.I835= | Silent (SNP) | VAF 112/150 reads (75%) | catalogued as rs782193529, COSV54856630; called by muse, mutect2, varscan2
- BCL9L | c.2235C>T p.G745= | Silent (SNP) | VAF 37/138 reads (27%) | catalogued as COSV99418292; called by muse, mutect2, varscan2
- C19orf57 | c.601T>C p.L201= | Silent (SNP) | VAF 44/163 reads (27%) | catalogued as rs1568379291, COSV60969600; called by muse, mutect2, varscan2
- CAMKMT | c.903G>A p.K301= | Silent (SNP) | VAF 11/74 reads (15%) | catalogued as COSV65928225; called by muse, mutect2, varscan2
- CAMSAP3 | c.864C>T p.S288= | Silent (SNP) | VAF 59/249 reads (24%) | catalogued as COSV50331779; called by muse, mutect2, varscan2
- CAND1 | c.1485C>T p.I495= | Silent (SNP) | VAF 28/126 reads (22%) | catalogued as rs771093103, COSV73389674; called by muse, mutect2, varscan2
- CDKN2B | c.210G>A p.A70= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as COSV52805675; called by muse, mutect2, varscan2
- CFAP251 | c.2421G>A p.R807= | Silent (SNP) | VAF 24/118 reads (20%) | catalogued as COSV56613954; called by muse, mutect2, varscan2
- CHAF1A | c.975C>T p.F325= | Silent (SNP) | VAF 34/91 reads (37%) | catalogued as rs143106881; called by muse, mutect2, varscan2
- CHST7 | c.1020C>T p.F340= | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as COSV52100900; called by muse, mutect2
- CIC | c.3573C>T p.S1191= | Silent (SNP) | VAF 20/43 reads (47%) | catalogued as rs573625418, COSV99358669; called by muse, mutect2, varscan2
- CLSTN2 | c.2004C>T p.F668= | Silent (SNP) | VAF 20/92 reads (22%) | catalogued as rs778778245, COSV71720462; called by muse, mutect2, varscan2
- CNTN3 | c.2007G>A p.V669= | Silent (SNP) | VAF 37/128 reads (29%) | catalogued as COSV55180271; called by muse, mutect2, varscan2
- CNTNAP2 | c.156C>T p.S52= | Silent (SNP) | VAF 33/69 reads (48%) | catalogued as COSV62231962; called by muse, mutect2, varscan2
- CTNND1 | c.612G>A p.R204= | Silent (SNP) | VAF 85/279 reads (30%) | catalogued as COSV62385216; called by muse, mutect2, varscan2
- DCLK3 | c.1305G>A p.Q435= | Silent (SNP) | VAF 25/117 reads (21%) | catalogued as COSV69364191, COSV99067416; called by muse, mutect2, varscan2
- DHX34 | c.2577C>T p.A859= | Silent (SNP) | VAF 4/8 reads (50%) | catalogued as COSV60897114; called by muse, mutect2, varscan2
- DNAH2 | c.4272G>A p.K1424= | Silent (SNP) | VAF 43/172 reads (25%) | catalogued as rs1255376306, COSV66720533; called by muse, mutect2, varscan2
- DNAH5 | c.6885G>A p.A2295= | Silent (SNP) | VAF 44/92 reads (48%) | catalogued as rs762437869, COSV54242772, COSV99443106; ClinVar: likely benign; called by muse, mutect2, varscan2
- DNAI1 | c.1440G>C p.V480= | Silent (SNP) | VAF 23/92 reads (25%) | catalogued as COSV54283365; called by muse, mutect2, varscan2
- DPP10 | c.2163A>C p.I721= | Silent (SNP) | VAF 36/174 reads (21%) | catalogued as COSV59709297; called by muse, mutect2, varscan2
- DSP | c.7824T>C p.S2608= | Silent (SNP) | VAF 101/155 reads (65%) | catalogued as COSV65794428; called by muse, mutect2, varscan2
- EP400 | c.8829C>T p.A2943= | Silent (SNP) | VAF 40/179 reads (22%) | catalogued as COSV57781419; called by muse, mutect2, varscan2
- ERBB2 | c.2775G>A p.G925= | Silent (SNP) | VAF 32/58 reads (55%) | catalogued as COSV54077959; called by muse, mutect2, varscan2
- ERC2 | c.2241C>T p.I747= | Silent (SNP) | VAF 33/168 reads (20%) | catalogued as rs750905847, COSV55614799; called by muse, mutect2, varscan2
- EXOG | c.675C>T p.P225= | Silent (SNP) | VAF 47/104 reads (45%) | catalogued as rs758843527, COSV55064290; called by muse, mutect2, varscan2
- FOXJ3 | c.1677C>T p.L559= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as COSV62364331; called by muse, mutect2, varscan2
- GALT | c.831C>T p.S277= | Silent (SNP) | VAF 98/240 reads (41%) | catalogued as rs755776140, COSV58840203; called by muse, mutect2, varscan2
- GAS2L2 | c.2443C>T p.L815= | Silent (SNP) | VAF 53/111 reads (48%) | catalogued as rs930805645; called by muse, mutect2, varscan2
- GAS2L3 | c.1947C>T p.G649= | Silent (SNP) | VAF 15/81 reads (19%) | catalogued as COSV57158476; called by muse, mutect2, varscan2
- GJA1 | c.1011C>T p.F337= | Silent (SNP) | VAF 29/128 reads (23%) | catalogued as COSV56999010; called by muse, mutect2, varscan2
- GJA8 | c.909G>A p.K303= | Silent (SNP) | VAF 23/53 reads (43%) | catalogued as COSV53789142; called by muse, mutect2, varscan2
- GMPPA | c.306C>T p.I102= | Silent (SNP) | VAF 32/189 reads (17%) | catalogued as COSV58008825; called by muse, mutect2, varscan2
- H4C9 | c.207C>T p.D69= | Silent (SNP) | VAF 43/141 reads (30%) | catalogued as COSV62890118; called by muse, mutect2, varscan2
- HABP2 | c.276G>A p.G92= | Silent (SNP) | VAF 55/191 reads (29%) | catalogued as rs768605771, COSV63637623; called by muse, mutect2, varscan2
- HAP1 | c.1554C>T p.S518= (on ENST00000310778 / NM_001367460.1; = p.S466= on NM_177977.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/118 reads (22%) | catalogued as COSV57879985; called by muse, mutect2, varscan2
- HDAC6 | c.1782C>T p.L594= | Silent (SNP) | VAF 26/36 reads (72%) | catalogued as COSV61930007; called by muse, mutect2, varscan2
- HHLA2 | c.237C>T p.D79= | Silent (SNP) | VAF 12/81 reads (15%) | catalogued as COSV63319059; called by muse, mutect2, varscan2
- HTR1D | c.525C>T p.F175= | Silent (SNP) | VAF 21/85 reads (25%) | catalogued as COSV58448775; called by muse, mutect2, varscan2
- IRF3 | c.939G>A p.K313= | Silent (SNP) | VAF 64/273 reads (23%) | catalogued as COSV55864203; called by muse, mutect2, varscan2
- IRX1 | c.1134A>C p.A378= | Silent (SNP) | VAF 35/76 reads (46%) | catalogued as COSV57361437; called by muse, mutect2, varscan2
- ITGA11 | c.1038G>A p.G346= | Silent (SNP) | VAF 25/78 reads (32%) | catalogued as COSV59880580; called by muse, mutect2, varscan2
- KCND3 | c.381C>T p.I127= | Silent (SNP) | VAF 30/84 reads (36%) | catalogued as COSV56186433; called by muse, mutect2, varscan2
- KCNJ3 | c.1440A>T p.G480= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV54541183; called by muse, mutect2, varscan2
- KRT78 | c.1554C>T p.I518= | Silent (SNP) | VAF 34/89 reads (38%) | catalogued as COSV57941602; called by muse, mutect2, varscan2
- LILRA4 | c.681G>A p.L227= | Silent (SNP) | VAF 19/66 reads (29%) | catalogued as COSV99392772; called by muse, mutect2, varscan2
- LIN7A | c.432A>G p.E144= | Silent (SNP) | VAF 25/100 reads (25%) | catalogued as COSV54025552; called by muse, mutect2, varscan2
- LRRC6 | c.72G>A p.E24= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as COSV51545586; called by muse, mutect2, varscan2
- LRRTM4 | c.1458G>A p.V486= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as COSV69141115; called by muse, mutect2, varscan2
- MEFV | c.36C>A p.T12= | Silent (SNP) | VAF 71/121 reads (59%) | catalogued as COSV54825656, COSV99561155; called by muse, mutect2, varscan2
- MGLL | c.531G>A p.G177= (on ENST00000398104 / NM_001003794.2; = p.G187= on NM_007283.6) | Silent (SNP) | VAF 3/10 reads (30%) | catalogued as COSV54028375; called by muse, mutect2
- MMP10 | c.189C>T p.I63= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV54247134; called by muse, mutect2, varscan2
- MUC16 | c.1248G>A p.E416= | Silent (SNP) | VAF 20/102 reads (20%) | catalogued as COSV67481922; called by muse, mutect2, varscan2
- MYH7 | c.1590C>T p.I530= | Silent (SNP) | VAF 18/78 reads (23%) | catalogued as COSV62522059; called by muse, mutect2, varscan2
- MYO5B | c.4908C>T p.T1636= | Silent (SNP) | VAF 55/103 reads (53%) | catalogued as rs772198023, COSV99543128; called by muse, mutect2, varscan2
- NFATC2 | c.2563C>T p.L855= | Silent (SNP) | VAF 52/190 reads (27%) | catalogued as COSV65359316; called by muse, mutect2, varscan2
- NHSL2 | c.1287G>A p.K429= (on ENST00000510661; = p.K795= on NM_001013627.2) | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as COSV65454409; called by muse, mutect2, varscan2
- NMU | c.196C>T p.L66= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as rs767944824, COSV51701241; called by muse, mutect2, varscan2
- NUAK1 | c.345C>T p.I115= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV54606500; called by muse, mutect2, varscan2
- NUP107 | c.669T>G p.A223= | Silent (SNP) | VAF 19/91 reads (21%) | catalogued as COSV57496803; called by muse, mutect2, varscan2
- OBSCN | c.17571C>T p.C5857= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as rs371176558; called by muse, mutect2
- OR13C2 | c.108G>A p.V36= | Silent (SNP) | VAF 36/139 reads (26%) | catalogued as COSV101604851; called by muse, mutect2, varscan2
- OR5K1 | c.534C>T p.Y178= | Silent (SNP) | VAF 123/315 reads (39%) | catalogued as COSV60304974; called by muse, mutect2, varscan2
- OR6C1 | c.711C>T p.S237= | Silent (SNP) | VAF 23/45 reads (51%) | catalogued as COSV65574176; called by muse, mutect2, varscan2
- PAK5 | c.1338G>A p.R446= | Silent (SNP) | VAF 46/148 reads (31%) | catalogued as COSV62034844; called by muse, mutect2, varscan2
- PCARE | c.1563G>A p.R521= | Silent (SNP) | VAF 27/142 reads (19%) | catalogued as COSV59056690; called by muse, mutect2, varscan2
- PDZD2 | c.6807C>T p.P2269= | Silent (SNP) | VAF 76/218 reads (35%) | catalogued as rs759093558, COSV99223116; called by muse, mutect2, varscan2
- PLA2G3 | c.1464C>T p.N488= | Silent (SNP) | VAF 128/173 reads (74%) | catalogued as rs1464423407, COSV53211758; called by muse, mutect2, varscan2
- PLCXD2 | c.795G>A p.A265= | Silent (SNP) | VAF 54/118 reads (46%) | catalogued as rs61755448, COSV67341645; called by muse, mutect2, varscan2
- PRAMEF19 | c.1170C>T p.S390= | Silent (SNP) | VAF 115/455 reads (25%) | called by muse, mutect2, varscan2
- PRMT5 | c.1410C>T p.S470= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV53547782; called by muse, mutect2, varscan2
- PRX | c.2946G>A p.E982= | Silent (SNP) | VAF 40/148 reads (27%) | catalogued as COSV52532320; called by muse, mutect2, varscan2
- PTBP1 | c.1350C>T p.F450= (on ENST00000349038 / NM_031991.4; = p.F476= on NM_002819.5) | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as COSV62459483; called by muse, mutect2, varscan2
- RANBP2 | c.7365G>C p.R2455= | Silent (SNP) | VAF 68/512 reads (13%) | catalogued as COSV51705826; called by muse, mutect2, varscan2
- RASAL2 | c.546C>T p.A182= | Silent (SNP) | VAF 55/125 reads (44%) | catalogued as rs371614679; called by muse, mutect2, varscan2
- RIPOR3 | c.159C>T p.S53= | Silent (SNP) | VAF 18/157 reads (11%) | catalogued as rs574924168, COSV50396958; called by muse, mutect2, varscan2
- SCN1A | c.2484C>T p.F828= (on ENST00000303395 / NM_001202435.3; = p.F817= on NM_006920.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as COSV57661756; called by muse, mutect2, varscan2
- SERPINI1 | c.696C>G p.S232= | Silent (SNP) | VAF 11/61 reads (18%) | catalogued as COSV55513438; called by muse, mutect2, varscan2
- SH2B1 | c.507C>T p.I169= | Silent (SNP) | VAF 36/118 reads (31%) | catalogued as rs753839467, COSV59465482; called by muse, mutect2, varscan2
- SLC9C1 | c.2844A>G p.G948= | Silent (SNP) | VAF 12/94 reads (13%) | catalogued as COSV59891341; called by muse, mutect2, varscan2
- SPATA5 | c.1593T>C p.D531= | Silent (SNP) | VAF 31/126 reads (25%) | catalogued as COSV56781253; called by muse, mutect2, varscan2
- STING1 | c.369C>T p.L123= | Silent (SNP) | VAF 28/106 reads (26%) | catalogued as COSV58173237; called by muse, mutect2, varscan2
- TBC1D32 | c.2673C>A p.L891= | Silent (SNP) | VAF 39/63 reads (62%) | catalogued as COSV51535765, COSV51550425; called by muse, mutect2, varscan2
- TDRD5 | c.2901G>A p.R967= | Silent (SNP) | VAF 17/80 reads (21%) | catalogued as COSV54247915; called by muse, mutect2, varscan2
- TECPR2 | c.1678C>T p.L560= | Silent (SNP) | VAF 32/77 reads (42%) | catalogued as COSV63972786; called by muse, mutect2, varscan2
- TNK2 | c.1836G>T p.L612= | Silent (SNP) | VAF 16/68 reads (24%) | catalogued as rs998895159, COSV57373929; called by muse, mutect2, varscan2
- TNPO2 | c.883C>T p.L295= | Silent (SNP) | VAF 12/119 reads (10%) | catalogued as COSV63509477; called by muse, mutect2, varscan2
- TRIO | c.8820T>G p.A2940= | Silent (SNP) | VAF 9/66 reads (14%) | catalogued as COSV59991881; called by muse, mutect2, varscan2
- TTLL6 | c.1827G>A p.R609= (on ENST00000393382 / NM_001130918.3; = p.R302= on NM_173623.3) | Silent (SNP) | VAF 29/115 reads (25%) | catalogued as COSV64978431; called by muse, mutect2, varscan2
- UCN3 | c.21C>T p.F7= | Silent (SNP) | VAF 125/170 reads (74%) | catalogued as COSV66824212; called by muse, mutect2, varscan2
- ULBP3 | c.342C>T p.F114= | Silent (SNP) | VAF 25/104 reads (24%) | catalogued as COSV66254104; called by muse, mutect2, varscan2
- USP29 | c.1041G>A p.K347= | Silent (SNP) | VAF 21/115 reads (18%) | catalogued as COSV54144230, COSV54145056; called by muse, mutect2, varscan2
- WFIKKN2 | c.774C>T p.N258= | Silent (SNP) | VAF 22/92 reads (24%) | catalogued as COSV60959752; called by muse, mutect2, varscan2
- WNK2 | c.4710G>A p.S1570= (on ENST00000297954 / NM_001282394.1; = p.S1533= on NM_006648.3) | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as rs750204095, COSV52950151; called by muse, mutect2, varscan2
- ZC4H2 | c.408G>A p.E136= | Silent (SNP) | VAF 35/61 reads (57%) | catalogued as COSV62005278; called by muse, mutect2, varscan2
- AP2A2 | c.*516C>T | 3'UTR (SNP) | VAF 10/35 reads (29%) | catalogued as COSV100172322; called by muse, mutect2, varscan2
- ATG2A | chr11:64891405 C>T | 3'Flank (SNP) | VAF 7/19 reads (37%) | called by muse, mutect2, varscan2
- FOLH1B | n.1301G>A | RNA (SNP) | VAF 9/43 reads (21%) | called by muse, mutect2, varscan2
- FRMPD2B | n.454C>A | RNA (SNP) | VAF 19/169 reads (11%) | called by muse, mutect2, varscan2
- MACF1 | c.15832-8111C>T | Intron (SNP) | VAF 14/47 reads (30%) | catalogued as rs1231565438, COSV57135481; called by muse, mutect2, varscan2
- MFSD12 | chr19:3542862 G>A | 3'Flank (SNP) | VAF 7/86 reads (8%) | catalogued as COSV61536456; called by muse, mutect2
- PTGER3 | c.*24-12952C>A | Intron (SNP) | VAF 18/63 reads (29%) | called by muse, mutect2, varscan2
- XIST | n.9961C>T | RNA (SNP) | VAF 19/29 reads (66%) | called by muse, mutect2, varscan2
